Gene-level copy-number profile of tumor specimen TCGA-CR-6477-01A from TCGA case TCGA-CR-6477, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Base of tongue, NOS; Tumor grade: G2; Age at diagnosis: 57.0 years (20,815 days).
Specimen TCGA-CR-6477-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.db6d641e-3a70-44e9-80f2-7e6dfc36f069.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CR-6477-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/106082d8-3ca5-4e8f-92a3-0ab3d9e1e870

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 27; copy number 2: 11,574; copy number 3: 23,167; copy number 4: 14,272; copy number 5: 8,084; copy number 6: 672; copy number 7: 1,501; copy number 8: 57; copy number 9: 97; copy number 10: 62; copy number 11: 50; copy number 13: 17; copy number 14: 13; copy number 17: 76; copy number 19: 84; copy number 20: 20; copy number 22: 23; copy number 26: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CR-6477-01A-11D-1869-01): tumor purity 0.29, ploidy 3.45, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:188,671,353–189,133,292, 7 genes: AL929288.2, RPS3AP9, AL691515.1, AL691515.2, LINC01035, CLPTM1LP1, GAPDHP75.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,011 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:31,409,565–31,583,306, 6 genes, copy number 7 (within-gene range 4–7): SERINC2, AC209007.1, RNU6-40P, LDC1P, Y_RNA, LINC01226.
- chr1:39,659,121–42,844,991, 104 genes, copy number 8–10 (within-gene range 5–10) (broad region; genes not listed).
- chr1:56,414,935–61,742,424, 58 genes, copy number 7–17: LINC01767, PLPP3, RPL21P23, RPL23AP85, AC099789.1, PRKAA2, FYB2, AL360295.1, C8A, C8B, AL161740.1, DAB1, AL390243.1, RPS20P5, DAB1-AS1, HNRNPA1P6, RPS26P15, AL445193.2, AL445193.1, AL357373.1, OMA1, AL035411.3, AL035411.2, RN7SL713P, TACSTD2, AL035411.1, MYSM1, AL136985.3, JUN, LINC01135, AL136985.2, AL136985.1, LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1, FGGY, MIR4711, AL035416.1, HOOK1, CYP2J2, RN7SL475P, C1orf87, PGBD4P8, LINC02778, LINC01748, AC099792.1, NFIA, NFIA-AS2, NFIA-AS1, AC099791.3, AC099791.4, AC099791.1, TM2D1, AC099791.2.
- chr1:61,816,419–61,852,602, 2 genes, copy number 7: RNU6-414P, RNU6-1177P.
- chr1:71,081,324–73,749,623, 19 genes, copy number 11 (within-gene range 6–11): ZRANB2-AS2, AL358453.1, NEGR1, AL354949.1, AL359821.1, NEGR1-IT1, GDI2P2, AL513166.1, RPL31P12, AL583808.1, RNU6-1246P, LINC02796, LINC02797, AL732618.1, KRT8P21, RN7SKP19, LINC01360, LINC02238, RNA5SP50.
- chr1:149,782,671–152,445,456, 149 genes, copy number 7 (broad region; genes not listed).
- chr1:154,469,772–154,678,345, 10 genes, copy number 7: SHE, AL162591.2, TDRD10, UBE2Q1, UBE2Q1-AS1, AL592078.2, CHRNB2, AL592078.1, ADAR, AL606500.1.
- chr1:159,712,289–161,309,968, 88 genes, copy number 9 (broad region; genes not listed).
- chr2:171,317,405–178,139,011, 151 genes, copy number 9–19 (within-gene range 4–19) (broad region; genes not listed).
- chr3:86,816,740–87,158,363, 4 genes, copy number 8: AC108706.1, VGLL3, PPATP1, LINC00506.
- chr5:23,951,348–24,178,263, 1 gene, copy number 7 (within-gene range 5–7): C5orf17.
- chr5:24,135,160–41,071,342, 249 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr5:43,874,367–44,828,592, 11 genes, copy number 10: AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2.
- chr7:70,972–57,275,197, 1,049 genes, copy number 7 (broad region; genes not listed).
- chr11:69,147,228–70,398,488, 37 genes, copy number 17–26 (within-gene range 4–26): AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1.
- chr13:33,333,679–33,966,558, 10 genes, copy number 11: LINC02344, AL138999.2, AL138999.1, AL139383.1, AL161719.1, AL139081.1, AL139081.2, RFC3, RNU5A-4P, AL161891.1.
- chr18:47,390–1,310,018, 39 genes, copy number 7–22: TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3.
- chr19:58,401,504–58,418,327, 1 gene, copy number 7 (within-gene range 4–7): ZNF584.
- chr19:58,418,560–58,605,223, 23 genes, copy number 7: AC012313.4, AC012313.5, ZNF132, AC012313.8, ZNF324B, ZNF324, ZNF446, AC012313.7, SLC27A5, RNU6-1337P, RN7SL693P, AC012313.9, ZBTB45, RN7SL525P, TRIM28, MIR6807, CHMP2A, UBE2M, MZF1-AS1, MZF1, CENPBD1P1, AC016629.3, AC016629.1.

Autosomal genes at a single copy (total copy number 1): 27. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
